Somatic mutation profile of tumor specimen HCM-CSHL-0084-C25-01A (aliquot HCM-CSHL-0084-C25-01A-11D-A78M-36) from HCMI case HCM-CSHL-0084-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.2 years (26,727 days).
Specimen HCM-CSHL-0084-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dc7ec75-5c52-4c35-87e6-4c0085429fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0084-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0084-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/163122f6-bb03-4875-b86e-c8d0399984a4

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 7, 5'UTR 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/318 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 121/359 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs150380425; called by muse, mutect2, varscan2
- CDC5L | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65176928; called by muse, mutect2, varscan2
- COL6A3 | c.5825C>T p.P1942L | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs150694150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.1633G>T p.V545L (on ENST00000297405 / NM_001363185.1; = p.V441L on NM_052900.3) | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99826970; called by muse, mutect2, varscan2
- CUBN | c.3616G>T p.E1206* | Nonsense Mutation (SNP) | VAF 34/407 reads (8%) | catalogued as COSV64711598, COSV64718159; called by muse, mutect2
- DCBLD1 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | catalogued as rs1186229621, COSV99757699; called by mutect2, varscan2
- DMD | c.5194G>T p.D1732Y | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1174588427; called by muse, mutect2, varscan2
- EGLN2 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs746648993, COSV58280174; called by muse, mutect2
- FLNC | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1357772572, COSV57956277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD4A | c.114C>A p.P38= | Splice Region (SNP) | VAF 24/132 reads (18%) | catalogued as COSV99198690; called by muse, mutect2, varscan2
- GPR37 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs763636472, COSV58256275; called by muse, mutect2, varscan2
- HMCN2 | c.11308G>A p.D3770N | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs889018911; called by muse, mutect2, varscan2
- IKBKE | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs150428746; called by muse, mutect2
- LAMC3 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 123/763 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242337882, COSV63092889; called by muse, mutect2, varscan2
- MARCHF11 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.06); catalogued as rs1488229935, COSV60131288; called by muse, mutect2, varscan2
- NLN | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 31/526 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs373507441; called by muse, mutect2
- NOL4 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs114980815; called by muse, mutect2, varscan2
- OLFM4 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54576255, COSV54577839, COSV54579863; called by muse, mutect2, varscan2
- PLEKHF2 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1039604415; called by muse, mutect2, varscan2
- PLEKHG4B | c.1384C>G p.R462G (on ENST00000283426; = p.R818G on NM_052909.5) | Missense Mutation (SNP) | VAF 74/668 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV52049808; called by muse, mutect2, varscan2
- SERPINE2 | c.1076-4G>A | Splice Region (SNP) | VAF 31/196 reads (16%) | catalogued as rs567218200; called by muse, mutect2, varscan2
- SLC47A1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs752921546, COSV54498987; called by muse, mutect2, varscan2
- SNTG2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1466380433; called by muse, mutect2, varscan2
- THBS4 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as rs553602331, COSV63470130; called by muse, mutect2, varscan2
- TMEM239 | c.146G>A p.R49Q (on ENST00000361033 / NM_001318207.1; = p.R6Q on NM_001167670.3) | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); catalogued as rs1010843980; called by muse, mutect2, varscan2
- ZDHHC20 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs761488863; called by muse, mutect2, varscan2
- ZFPM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100128299; called by muse, mutect2, varscan2
- ACO1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- ANKRD30B | c.1091A>T p.E364V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF7 | c.1577T>G p.L526R (on ENST00000375741 / NM_001113511.2; = p.L348R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- CDKN2A | c.334_337del p.R112Cfs*33 | Frame Shift Del (DEL) | VAF 99/570 reads (17%) | called by mutect2, pindel, varscan2
- CENPU | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- CLEC9A | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FAM118B | c.697-15_730del p.X233_splice | Splice Site (DEL) | VAF 24/176 reads (14%) | called by mutect2, pindel
- FATE1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FBN1 | c.6101G>A p.G2034D | Missense Mutation (SNP) | VAF 121/580 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FUZ | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FXR1 | c.353dup p.N118Kfs*2 | Frame Shift Ins (INS) | VAF 64/335 reads (19%) | called by mutect2, pindel, varscan2
- GATA2 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 41/471 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GSTA5 | c.133del p.R45Efs*19 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, varscan2
- MYOZ3 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PAQR9 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 48/537 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- SLC26A7 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); called by muse, mutect2
- STMN2 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM14 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM23 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZSCAN5C | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CREBBP | c.3132A>G p.E1044= | Silent (SNP) | VAF 88/523 reads (17%) | called by muse, mutect2, varscan2
- EDNRB | c.798G>C p.L266= (on ENST00000377211 / NM_001201397.1; = p.L176= on NM_000115.5) | Silent (SNP) | VAF 87/308 reads (28%) | called by muse, mutect2, varscan2
- LPAR6 | c.993G>A p.Q331= | Silent (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- MYO15A | c.102G>A p.S34= | Silent (SNP) | VAF 36/436 reads (8%) | catalogued as COSV99230580; called by muse, mutect2
- PEG3 | c.240C>T p.R80= | Silent (SNP) | VAF 49/347 reads (14%) | called by muse, mutect2, varscan2
- SEC14L5 | c.546G>T p.T182= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV99229472; called by muse, mutect2, varscan2
- TIMM44 | c.211T>C p.L71= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- ACAD8 | c.491-17T>C | Intron (SNP) | VAF 66/538 reads (12%) | called by muse, varscan2
- NDUFA2 | c.-41_-25del | 5'UTR (DEL) | VAF 145/856 reads (17%) | called by mutect2, pindel, varscan2
- PDE7B | c.711+202G>A | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918969 C>T | 5'Flank (SNP) | VAF 93/823 reads (11%) | catalogued as rs1243523510; called by muse, mutect2, varscan2
- SAP30 | c.-66G>A | 5'UTR (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- TCP10L2 | n.192C>T | RNA (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- ZNF606 | c.-540C>T | 5'UTR (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
